Somatic mutation profile of tumor specimen TCGA-D7-A6EV-01A (aliquot TCGA-D7-A6EV-01A-11D-A31L-08) from TCGA case TCGA-D7-A6EV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.8 years (26,226 days).
Specimen TCGA-D7-A6EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fad37ad-e611-45b6-b112-b9425943cce5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6EV-10A (Blood Derived Normal), aliquot TCGA-D7-A6EV-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da97114f-86e4-442d-a7e1-e0963e820f03

The open-access MAF lists 165 somatic variants for this specimen: 123 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 38, Frame Shift Del 6, Nonsense Mutation 5, Splice Region 4, Intron 3, Splice Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACOX3 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs759241743, COSV62712168; called by muse, mutect2
- APOB | c.8254G>T p.V2752L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV99266296; called by muse, mutect2, varscan2
- ARHGAP35 | c.2227G>A p.G743R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs1290155642, COSV101351256, COSV101351651; called by muse, mutect2, varscan2
- BAZ1B | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100289869; called by muse, mutect2, varscan2
- BCAT2 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV60272233; called by muse, mutect2, varscan2
- BDP1 | c.6022G>A p.V2008I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs1393749764, COSV100703259, COSV62431760; called by muse, mutect2
- BICD2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs758588310, COSV100794159; called by muse, mutect2, varscan2
- CCDC8 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100282087; called by muse, mutect2, varscan2
- CHD2 | c.4710C>G p.D1570E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101245495, COSV67706944; called by muse, mutect2, varscan2
- CKAP5 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100370933; called by muse, mutect2, varscan2
- COL14A1 | c.3524C>T p.S1175L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as rs369127166; called by muse, mutect2
- CRB1 | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100959035; called by muse, mutect2
- CRB1 | c.2560G>C p.D854H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553261618, COSV100957705, COSV100957940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.2843T>G p.V948G (on ENST00000297405 / NM_001363185.1; = p.V844G on NM_052900.3) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV99838140; called by muse, mutect2, varscan2
- CXXC1 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as COSV99496585; called by muse, mutect2, varscan2
- CYLC2 | c.728A>C p.K243T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100872477; called by muse, mutect2, varscan2
- DDI2 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100197692; called by muse, mutect2, varscan2
- DGKI | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.009); catalogued as rs1357077964, COSV99935527; called by muse, mutect2
- DNAH7 | c.2705A>T p.E902V | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415905; called by muse, mutect2, varscan2
- DNAH8 | c.9309C>G p.D3103E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.405); catalogued as COSV100545987; called by muse, mutect2, varscan2
- DOCK2 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs529505036, COSV99913384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTYK | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs143877075; called by muse, mutect2, varscan2
- DYSF | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs535367520, COSV99248091; ClinVar: uncertain significance; called by muse, mutect2
- ERBIN | c.3148C>G p.P1050A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99397154; called by muse, mutect2, varscan2
- EVC2 | c.2093G>C p.R698P | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV100186259; called by muse, mutect2
- F2R | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs771205478, COSV100058516; called by muse, mutect2, varscan2
- FAT3 | c.2858C>A p.T953N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99967378; called by muse, mutect2, varscan2
- FEM1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100183695; called by muse, mutect2, varscan2
- FERD3L | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762396; called by muse, mutect2, varscan2
- FREM2 | c.8237A>G p.K2746R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.072); catalogued as COSV99749301; called by muse, mutect2
- FZD2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59528128; called by muse, mutect2, varscan2
- GPR142 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs562453696, COSV100170869, COSV59519210; called by muse, mutect2, varscan2
- GREB1 | c.2705T>C p.V902A | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV99303165; called by muse, mutect2, varscan2
- GUCY2F | c.1032A>G p.Q344= | Splice Region (SNP) | VAF 43/87 reads (49%) | catalogued as COSV99485216; called by muse, mutect2, varscan2
- HECW1 | c.4131G>C p.L1377F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101223888; called by muse, mutect2, varscan2
- HIC2 | c.1009_1011del p.K337del | In Frame Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1568944191; called by pindel, varscan2
- HMOX1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs374813554; called by muse, mutect2
- HOMER1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99981180; called by muse, mutect2, varscan2
- HPD | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs375336061, COSV100000143; called by muse, mutect2, varscan2
- HS6ST3 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200597659, COSV100940919; called by muse, mutect2, varscan2
- ITGAX | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99191803; called by muse, mutect2, varscan2
- ITGBL1 | c.1457A>G p.E486G | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs765590693, COSV101086756; called by muse, mutect2
- IWS1 | c.1929G>T p.E643D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.376); catalogued as COSV99040023; called by muse, mutect2, varscan2
- KCNK5 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100851879; called by muse, mutect2, varscan2
- KCNMA1 | c.804G>T p.W268C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99698226; called by muse, mutect2, varscan2
- KIAA1549L | c.2381G>A p.R794Q (on ENST00000321505; = p.R1091Q on NM_012194.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55772245; called by muse, mutect2
- KRTAP19-5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs112006874, COSV61858873; called by muse, mutect2
- LAG3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV52566628; called by muse, mutect2, varscan2
- LAMA4 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV100038715; called by muse, mutect2, varscan2
- LCT | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99929771; called by muse, mutect2, varscan2
- LIN7A | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs147965628; called by muse, mutect2, varscan2
- LINGO2 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV100430741, COSV58056887; called by muse, mutect2, varscan2
- LONP2 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs758285618, COSV99589323; called by muse, mutect2, varscan2
- LRP1B | c.660T>A p.N220K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV101257937; called by muse, mutect2, varscan2
- LRRC32 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99477045; called by muse, mutect2
- LUM | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV99899090; called by muse, mutect2, varscan2
- MAP3K19 | c.3424T>C p.F1142L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100208770; called by muse, mutect2
- MAP3K8 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs201540136, COSV53922411; called by muse, mutect2, varscan2
- MBNL2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs896330931, COSV100600471; called by muse, mutect2, varscan2
- MED12L | c.2145G>A p.L715= | Splice Region (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99853674; called by muse, mutect2, varscan2
- METTL22 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as rs754423164, COSV50839297; called by muse, mutect2
- MTFMT | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV99584396; called by muse, mutect2, varscan2
- MTR | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764999575, COSV63963791; called by muse, mutect2, varscan2
- MUC16 | c.31036C>A p.P10346T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.937); catalogued as COSV101200291; called by muse, mutect2, varscan2
- MYH14 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771031207, COSV99223186; called by muse, mutect2, varscan2
- NAIF1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100895813; called by muse, mutect2
- NCAPG | c.1781T>G p.I594R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs1174967368, COSV99266055; called by muse, mutect2, varscan2
- NCLN | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs774615288, COSV99859999; called by muse, mutect2, varscan2
- NEFL | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764562926, COSV99648028; called by muse, mutect2, varscan2
- NF1 | c.6617C>G p.T2206R (on ENST00000358273 / NM_001042492.3; = p.T2185R on NM_000267.3) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100647445; called by muse, mutect2, varscan2
- OPCML | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770223558, COSV59410726; called by muse, mutect2, varscan2
- OR10G9 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100901667; called by muse, mutect2, varscan2
- OR4N2 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as rs1390482228, COSV60051082; called by muse, mutect2, varscan2
- OR5D16 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755221016, COSV65722006; called by muse, mutect2, varscan2
- OTUD7A | c.1603C>A p.L535M (on ENST00000307050 / NM_001382637.1; = p.L528M on NM_130901.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100192725; called by muse, mutect2, varscan2
- PACC1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as rs200795875; called by muse, mutect2, varscan2
- PCDHA11 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV56543098; called by muse, mutect2, varscan2
- PCDHB6 | c.2314T>G p.F772V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.23); catalogued as COSV50692394, COSV50740114; called by muse, mutect2, varscan2
- PLD1 | c.1338G>A p.K446= | Splice Region (SNP) | VAF 9/69 reads (13%) | catalogued as rs1327165866, COSV100578377; called by muse, mutect2, varscan2
- PRPF6 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs771579599, COSV53879938; called by muse, mutect2, varscan2
- PRR7 | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99446210; called by muse, mutect2, varscan2
- RASGEF1C | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs567856268, COSV100746077; called by muse, mutect2, varscan2
- RBKS | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99941428; called by muse, mutect2
- SELENOO | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.052); catalogued as rs759911721, COSV101096901; called by muse, mutect2, varscan2
- SLC2A6 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99390344; called by muse, mutect2
- SLC34A2 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs752794996, COSV65940658; called by muse, mutect2, varscan2
- SLC49A3 | c.1051G>A p.G351R (on ENST00000404286 / NM_001294341.2; = p.G350R on NM_032219.4) | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777697325, COSV100448301, COSV100448490; called by muse, mutect2, varscan2
- SMAD4 | c.1512T>G p.S504R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61689102, COSV61689588; called by muse, mutect2, varscan2
- SMG6 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99558377; called by muse, mutect2
- SORCS1 | c.2171C>G p.T724S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as COSV99547753; called by muse, mutect2, varscan2
- SST | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.454); catalogued as COSV55031205, COSV99809884; called by muse, mutect2, varscan2
- SUPT5H | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100782100; called by muse, mutect2, varscan2
- TBX10 | c.867A>C p.K289N | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100039811; called by muse, mutect2
- TEAD4 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.143); catalogued as rs929337081, COSV63279915; called by muse, mutect2
- TECTA | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99880293; called by muse, mutect2, varscan2
- TENM4 | c.3874G>A p.V1292I | Missense Mutation (SNP) | VAF 97/116 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs776483085, COSV53651831; called by muse, mutect2, varscan2
- TG | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.186); catalogued as COSV99601639; called by muse, mutect2
- TLE2 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758323007, COSV53582593, COSV99504461; called by muse, mutect2, varscan2
- TMEM230 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177004; called by muse, mutect2, varscan2
- TOPBP1 | c.3461G>C p.R1154T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99605485; called by muse, mutect2, varscan2
- TTN | c.28811T>C p.I9604T (on ENST00000591111; = p.I8677T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | PolyPhen benign (0.21); catalogued as rs373651676; ClinVar: uncertain significance; called by muse, mutect2
- TUSC3 | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV101141925, COSV65887529; called by muse, mutect2
- USP28 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs749211347, COSV50177159, COSV99135670; called by muse, mutect2, varscan2
- VPS4A | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV99652021; called by muse, mutect2
- WWP2 | c.1831T>C p.F611L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100598610; called by muse, mutect2, varscan2
- ZC3H13 | c.1778A>C p.H593P | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99668403; called by muse, mutect2, varscan2
- ZIC5 | c.1846C>G p.Q616E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV99940601; called by muse, mutect2
- ZNF175 | c.1176A>T p.E392D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV99219583; called by muse, mutect2, varscan2
- ZNF418 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101268949; called by muse, mutect2, varscan2
- ABCB1 | c.96_99del p.T33Sfs*35 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- ACTL9 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2
- ARHGAP30 | c.1758del p.S587Afs*24 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- FPR1 | c.568_569del p.R190Dfs*45 | Frame Shift Del (DEL) | VAF 42/74 reads (57%) | called by pindel, varscan2
- IFNA2 | c.468_471del p.K156Nfs*15 | Frame Shift Del (DEL) | VAF 44/178 reads (25%) | called by mutect2, pindel, varscan2
- JAK2 | c.914_917del p.E305Vfs*4 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- MUC2 | c.3478C>A p.L1160M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MUC6 | c.6560_6572del p.P2187Qfs*51 | Frame Shift Del (DEL) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- MYH9 | c.5554_5557dup p.D1853Gfs*2 | Nonsense Mutation (INS) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- NAA25 | c.2796G>C p.P932= | Splice Region (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- PDE10A | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- PRAMEF8 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- TNFRSF8 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2
- ALMS1 | c.12180G>A p.K4060= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100042860; called by muse, mutect2, varscan2
- AMBRA1 | c.1815C>T p.S605= (on ENST00000458649 / NM_001367468.1; = p.S515= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100094411; called by muse, mutect2, varscan2
- ANGPT1 | c.672T>C p.T224= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV99863262; called by muse, mutect2
- ASGR1 | c.675C>T p.D225= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV99352552; called by muse, mutect2, varscan2
- ATCAY | c.294C>T p.I98= | Silent (SNP) | VAF 67/107 reads (63%) | catalogued as rs1203087843, COSV56654459; called by muse, mutect2, varscan2
- C8orf74 | c.540C>T p.A180= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs765971938, COSV100262139; called by muse, mutect2
- CEPT1 | c.798C>T p.F266= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV100718705; called by muse, mutect2, varscan2
- COPA | c.3354C>T p.F1118= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99616041; called by muse, mutect2
- DRC7 | c.1950G>A p.T650= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as rs1360875569, COSV100395689; called by muse, mutect2
- EBF2 | c.213G>A p.L71= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV101282231; called by muse, mutect2
- FAM135B | c.3681C>T p.V1227= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV99425100; called by muse, mutect2
- FAM135B | c.1878G>A p.G626= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as rs559587758, COSV99425103; called by muse, mutect2
- FAM83H | c.1419C>T p.F473= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV66354681; called by muse, mutect2
- GAS2L1 | c.1843C>T p.L615= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs769189937, COSV99329580; called by muse, mutect2, varscan2
- GRIN2D | c.3405C>T p.A1135= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV53517862, COSV99474568; called by muse, mutect2, varscan2
- INPP5A | c.771C>T p.A257= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs765991979, COSV61246548; called by muse, mutect2, varscan2
- IRS1 | c.2103C>T p.N701= | Silent (SNP) | VAF 37/205 reads (18%) | catalogued as rs772248279, COSV59334046; called by muse, mutect2, varscan2
- LRFN2 | c.777C>T p.D259= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs759825037, COSV57825653, COSV57833566; called by muse, mutect2, varscan2
- MUC17 | c.9168G>A p.T3056= | Silent (SNP) | VAF 198/1450 reads (14%) | catalogued as rs908631374, COSV100073938, COSV60305768; called by muse, mutect2, varscan2
- NDUFA7 | c.276G>A p.K92= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100035570; called by muse, mutect2, varscan2
- NR1I2 | c.1107C>T p.F369= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs369188703; called by muse, mutect2, varscan2
- NSD2 | c.2037C>G p.L679= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100373544; called by muse, mutect2, varscan2
- OLFM4 | c.900G>A p.L300= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs750289863, COSV99524418; called by muse, mutect2, varscan2
- OR5T3 | c.348T>C p.F116= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV100282851; called by muse, mutect2, varscan2
- PLEKHA4 | c.462G>A p.A154= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV54365178; called by muse, mutect2
- RAB33B | c.195G>T p.T65= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99978218; called by muse, mutect2, varscan2
- RTL6 | c.672C>T p.N224= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs761828149, COSV100373810; called by muse, mutect2, varscan2
- SCML4 | c.372C>T p.P124= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs751899100, COSV100940348; called by muse, mutect2, varscan2
- SUPT5H | c.2304G>A p.T768= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs374930575; called by muse, mutect2, varscan2
- TPPP | c.264C>G p.G88= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs774409762, COSV100862849; called by muse, mutect2, varscan2
- TTC23 | c.1020C>T p.S340= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1220078489, COSV100018934; called by muse, mutect2, varscan2
- TTN | c.33006A>G p.T11002= (on ENST00000591111; = p.T10075= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100618632; called by muse, mutect2
- TTN | c.12858G>A p.E4286= (on ENST00000591111; = p.E4240= on NM_003319.4) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs770564701, COSV100618635; called by muse, mutect2, varscan2
- UNC119 | c.339G>C p.R113= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99971738; called by muse, mutect2, varscan2
- UTP18 | c.669T>C p.N223= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99834821; called by muse, mutect2, varscan2
- VCL | c.2907G>A p.A969= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99280993; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1047C>T p.P349= | Silent (SNP) | VAF 77/229 reads (34%) | catalogued as COSV57638143; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1582T>G | RNA (SNP) | VAF 5/44 reads (11%) | catalogued as COSV101181739; called by muse, mutect2, varscan2
- ITIH5 | c.2032+764G>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as COSV53662799; called by muse, mutect2
- LY9 | c.454+1736C>T | Intron (SNP) | VAF 24/174 reads (14%) | catalogued as rs1417473725, COSV99626948; called by muse, mutect2, varscan2
- NTRK3 | c.1890-1785A>G | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as rs758239524, COSV62316904; called by muse, mutect2, varscan2
